Gene-level copy-number profile of tumor specimen TCGA-MA-AA3W-01A from TCGA case TCGA-MA-AA3W, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G3; Age at diagnosis: 54.9 years (20,066 days).
Specimen TCGA-MA-AA3W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.17711746-6187-4c56-b0b5-d4f34e5a8bc5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-MA-AA3W-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/64632aac-fe0d-4bdb-a0bd-955b7ec64c9c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 4; copy number 2: 5,780; copy number 3: 4,481; copy number 4: 40,199; copy number 5: 1,437; copy number 6: 7,065; copy number 7: 29; copy number 8: 165; copy number 9: 638; copy number 15: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-MA-AA3W-01A-11D-A386-01): tumor purity 0.48, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 654 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:164,001,606–198,222,513, 638 genes, copy number 9 (broad region; genes not listed).
- chr10:100,907,174–101,137,789, 16 genes, copy number 15: Y_RNA, AL138762.1, SLF2, AL133215.3, MRPL43, SEMA4G, MIR608, AL133215.1, TWNK, LZTS2, PDZD7, SFXN3, AL133215.2, KAZALD1, TLX1NB, TLX1.

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
